Gene-level copy-number profile of tumor specimen TCGA-B5-A11R-01A from TCGA case TCGA-B5-A11R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.7 years (18,878 days).
Specimen TCGA-B5-A11R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.8839f1c4-e541-4022-b494-dd2e8bf4aa33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A11R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43cea8f8-00e2-4806-a41b-2578351473aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 40,120; copy number 3: 2,981; copy number 6: 14,106; copy number 7: 9; copy number 11: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A11R-01A-11D-A120-01): tumor purity 0.82, ploidy 2.36, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16,719 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 11 (broad region; genes not listed).
- chr3:11,745–198,222,513, 3,185 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–170,738,536, 3,061 genes, copy number 6 (broad region; genes not listed).
- chr8:150,584–145,066,685, 2,481 genes, copy number 6 (broad region; genes not listed).
- chr10:44,712–133,761,125, 2,329 genes, copy number 6 (within-gene range 6–18) (broad region; genes not listed).
- chr12:66,767–133,214,832, 3,050 genes, copy number 6 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 2–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr16:79,202,624–79,516,293, 5 genes, copy number 7: AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
